Somatic mutation profile of tumor specimen ALCH-B2W1-TTP1-A (aliquot ALCH-B2W1-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2W1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.4 years (26,091 days).
Specimen ALCH-B2W1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e22803ac-8728-462a-b8de-70ffe3cc9b27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2W1-NB1-A (Blood Derived Normal), aliquot ALCH-B2W1-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6a67efa-01f1-4042-a298-ccab5df86075

The open-access MAF lists 59 somatic variants for this specimen: 40 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 16, Nonsense Mutation 4, Splice Region 2, 5'UTR 1, In Frame Del 1, 3'UTR 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 79/711 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ALDH3A2 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs763232206; called by muse, mutect2
- AMDHD2 | c.971-4C>T | Splice Region (SNP) | VAF 17/225 reads (8%) | catalogued as rs759930610; called by muse, mutect2
- ATN1 | c.1946A>T p.Y649F | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.048); catalogued as rs781963846, COSV100755963; called by muse, mutect2, varscan2
- CAMTA2 | c.2386G>A p.V796M | Missense Mutation (SNP) | VAF 49/570 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1285939734; called by muse, mutect2
- GBA | c.1264C>A p.L422I | Missense Mutation (SNP) | VAF 25/417 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.832); catalogued as rs187143994; called by muse, mutect2
- GRM8 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100279655; called by muse, mutect2
- MARCHF4 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1410905109, COSV56107808; called by muse, mutect2
- PCDH11X | c.3052C>T p.R1018* | Nonsense Mutation (SNP) | VAF 24/144 reads (17%) | catalogued as rs779299402, COSV53487511; called by muse, mutect2, varscan2
- PCDH19 | c.2011T>G p.S671A | Missense Mutation (SNP) | VAF 26/740 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55262392; called by muse, mutect2
- TAF1L | c.4186C>T p.R1396C | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs535208015, COSV54265096; called by muse, varscan2
- TMEM179 | c.522+6G>T | Splice Region (SNP) | VAF 20/176 reads (11%) | catalogued as rs766086079; called by muse, mutect2
- TNRC6A | c.4805G>C p.G1602A | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV100169838; called by muse, mutect2
- TONSL | c.3454C>T p.L1152F | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs1313610367; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2418A>T p.L806F | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- C2CD3 | c.6751A>G p.I2251V | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- CREBBP | c.6346C>T p.Q2116* | Nonsense Mutation (SNP) | VAF 38/602 reads (6%) | called by muse, mutect2
- CSMD1 | c.8510C>T p.S2837F (on ENST00000520002; = p.S2836F on NM_033225.6) | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- CYP2C18 | c.1193A>G p.D398G | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- DEF6 | c.1858C>G p.P620A | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- DEFB128 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 14/288 reads (5%) | called by muse, mutect2
- ERRFI1 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 14/383 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GLIS1 | c.597G>A p.W199* | Nonsense Mutation (SNP) | VAF 27/372 reads (7%) | called by muse, mutect2
- HDAC3 | c.403C>G p.H135D | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPRIPL1 | c.1215C>A p.F405L (on ENST00000439118 / NM_001008949.3; = p.F413L on NM_178495.6) | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.396); called by muse, mutect2
- NACA | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- NRXN2 | c.2580T>G p.I860M | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ODR4 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, varscan2
- PFKM | c.747+2T>C p.X249_splice | Splice Site (SNP) | VAF 50/484 reads (10%) | called by muse, mutect2
- PRICKLE4 | c.880C>A p.P294T (on ENST00000359201; = p.P334T on NM_013397.6) | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); called by muse, mutect2
- RSF1 | c.131T>G p.F44C | Missense Mutation (SNP) | VAF 48/495 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SCOC | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 41/398 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SP140 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- TAFA1 | c.34T>C p.Y12H | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.102); called by muse, mutect2
- U2SURP | c.2700_2714del p.D901_L905del | In Frame Del (DEL) | VAF 7/74 reads (9%) | called by mutect2, pindel
- UBTD1 | c.574T>G p.F192V | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- UNC13A | c.5060T>C p.L1687P | Missense Mutation (SNP) | VAF 21/243 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- YY1AP1 | c.1619T>C p.F540S (on ENST00000295566 / NM_139118.2; = p.F483S on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2
- ZNF527 | c.911G>C p.C304S | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF551 | c.1045A>G p.N349D | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.009); called by muse, mutect2
- CTNND1 | c.1071G>C p.G357= | Silent (SNP) | VAF 25/326 reads (8%) | called by muse, mutect2
- DKC1 | c.486T>C p.A162= | Silent (SNP) | VAF 35/262 reads (13%) | called by muse, mutect2, varscan2
- EN2 | c.501C>A p.A167= | Silent (SNP) | VAF 18/274 reads (7%) | called by muse, mutect2
- FUBP3 | c.1695G>T p.A565= | Silent (SNP) | VAF 42/185 reads (23%) | catalogued as rs372811310; called by muse, mutect2, varscan2
- HASPIN | c.171C>T p.P57= | Silent (SNP) | VAF 12/163 reads (7%) | catalogued as COSV99561047; called by muse, mutect2
- LRRC55 | c.105C>T p.G35= | Silent (SNP) | VAF 19/247 reads (8%) | called by muse, mutect2
- MUC6 | c.1089C>T p.G363= | Silent (SNP) | VAF 15/178 reads (8%) | catalogued as rs372461474; called by muse, mutect2
- NEBL | c.303T>A p.L101= | Silent (SNP) | VAF 25/268 reads (9%) | called by muse, mutect2
- PACSIN1 | c.696G>A p.E232= | Silent (SNP) | VAF 17/279 reads (6%) | catalogued as rs769643796; called by muse, mutect2
- PAPPA | c.3540C>G p.S1180= | Silent (SNP) | VAF 64/477 reads (13%) | catalogued as COSV60277227, COSV60277610; called by muse, mutect2, varscan2
- PTPRN | c.24G>A p.G8= | Silent (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- RUBCNL | c.1194T>A p.S398= | Silent (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- SLC4A5 | c.1677C>T p.G559= | Silent (SNP) | VAF 22/219 reads (10%) | catalogued as rs777125943; called by muse, mutect2
- STK36 | c.807G>A p.L269= | Silent (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- TSEN54 | c.978C>T p.N326= | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as rs936793986; called by muse, mutect2
- UBE3C | c.6C>T p.F2= | Silent (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
- CLEC7A | c.*3G>C | 3'UTR (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- POU3F4 | chrX:83508283 T>G | 5'Flank (SNP) | VAF 81/314 reads (26%) | called by muse, mutect2, varscan2
- TNFRSF14 | c.-101T>G | 5'UTR (SNP) | VAF 10/183 reads (5%) | called by muse, mutect2
